Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A85I, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A85I-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: There is a skin flap with a black node on the broad base up to 4 x 3.5 cm in its size, 1 cm thick.

Microscopic Description: Malignant melanoma of the skin with superficial ulceration. Tumor Breslow thickness is 1 cm.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, hip

Tumor size: 3.5 x 1 x 4 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Breslow thickness is 1 cm.

Comments: None

ICD O-3
Melanoma, malignant NOS
Site Skin hip
8720/3
C44.7
AD 4/14/14

agnosis Discrepancy		
inary Tumor Site Discrepancy		
PAA Discrepancy		
for Malignancy History		
se is (c) (4)		
viewer		

10/24/13

Source: NCI Genomic Data Commons file edcac787-b15d-4aa9-a212-b6ed37a4fa71 (TCGA-EB-A85I.D35BCE2A-8132-4CAA-8E22-559B68BDAF07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).